Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A40Y, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A40Y-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY (Orders: [REDACTED])

Patient Info

Patient Name

Sex

DOB

Results

Specimen #: [REDACTED]
Submitting Physician:

FINAL DIAGNOSIS

1. Kidney, right, nephrectomy (A) - Renal cell carcinoma, papillary type, with focal sarcomatoid differentiation, Fuhrman nuclear grade 4 (8.5 cm in greatest dimension).
- Microscopic angiolymphatic invasion is identified.
- The tumor invades into the renal sinus.
- All surgical margins are negative.
- See template.
2. Lymph node, retrocaval, excision (B) - Two of seven lymph nodes positive for metastatic papillary renal cell carcinoma (2/7).
3. Adrenal gland, right, excision (C) - Unremarkable adrenal gland, negative for carcinoma.

COMMENT

Renal Cell Carcinoma; Kidney nephrectomy template

Procedure: Radical nephrectomy (with adrenal gland)

Specimen Laterality: Right

Tumor Site:
Upper pole
Middle

ICD-O-3

Renal cell carcinoma, papillary
8260/3

Tumor Size: 8.5 x 7.6 x 6.0 cm.

Site: Kidney, NOS

C64.9 8-3-12
RO

Tumor Focality: Unifocal

Macroscopic Extent of Tumor: (select all that apply)
Tumor extension into renal sinus

Histologic Type: Papillary renal cell carcinoma

Sarcomatoid Features: Present

Specify percentage of sarcomatoid element: less than 5%

Tumor Necrosis: Present

Histologic Grade: (Fuhrman Nuclear Grade): 4
Microscopic Tumor Extension: (select all that apply)

HIFAA Discrepancy		
Dual/Syncytic Primary Nuclei		

[page 2 of 3]
Tumor extension into renal sinus

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Present

Pathologic Findings in Nonneoplastic Kidney: (select all that apply)

Significant pathologic alterations

None identified

Pathologic Staging (pTNM)

TNM Descriptors: (required only if applicable) (select all that apply)

Primary Tumor: (pT): pT3a: Tumor grossly extends into the renal vein or its segmental (muscle containing) branches, or tumor invades perirenal and/or renal sinus fat but not beyond Gerota's fascia

Regional Lymph Nodes: (pN) pN1

pN1: Metastasis in regional lymph node(s)

Number examined: 7

Number positive: 2

Distant Metastasis: (pM) pMX

Not applicable

pMX:

(Electronic Signature)

SPECIMEN SUBMITTED

A: RIGHT KIDNEY

B: RETRO CAVAL LYMPH NODE

C: RIGHT ADRENAL GLAND

CLINICAL DATA

RIGHT RENAL MASS

GROSS DESCRIPTION

A. The specimen consists of a right kidney surrounded by an envelope of fibroadipose tissue measuring 15 x 9.8 x 6.2 cm and weighing 460 grams. The kidney measures 11.5 x 9.5 x 6 cm. An 8.5 x 7.6 x 6 cm mass involves the upper and mid portions of the kidney. On section, the tumor mass is roughly spherical and golden yellow in color with foci of hemorrhage and softening. The tumor essentially obliterates the renal sinus and does appear to involve the renal sinus fat. The tumor does not definitely extend into the perirenal fat and is not present at the soft tissue line of the specimen. The tumor does invade into the pyelocalyceal system and renal sinus. The tumor does appear to involve the renal capsule. The tumor is sharply demarcated from the renal parenchyma, which appears essentially unremarkable. Satellite nodules of tumor are not present in the renal tissue. Dissection of the renal veins, particularly those draining the area of neoplasm, do not show the intravascular presence of mass. The adrenal

[page 3 of 3]
gland is not present. A 4 cm segment of ureter is present and is essentially unremarkable. Lymph nodes are not present. Sections are submitted as follows: A1 ureteral margin; A2 vascular margin; A3-7 tumor nearest renal capsule and surrounding soft tissue (nearest soft tissue margin is in A7); A8-10 tumor in renal sinus.

B. Received in formalin labeled "retrocaval lymph nodes" are multiple irregular segments of fibroadipose tissue aggregating to 4.5 x 1.5 x 1.0 cm. Evidence of cautery is identified. On palpation, three tan-pink firm nodules are identified ranging in size from 1.1 to 2.3 cm in greatest dimension. The nodules are totally submitted in formalin as follows: B1 one nodule bisected, totally submitted, B2 one nodule bisected, totally submitted, B3 one nodule bisected, totally submitted.

C. Received in formalin labeled "right adrenal gland" is an adrenal gland measuring 8.0 x 3.0 x 1.0 cm and weighing 14.0 grams. Sutures are present on one aspect of the specimen. Upon sectioning, a tan gelatinous nodule is present measuring 0.4 cm in greatest dimension. No other lesions are identified. A photograph is taken. Representative sections are submitted in formalin as follows: C1-C2 nodule, C3-C4 additional random representative sections.

Patient ID #: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Date of Report: [REDACTED]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Submitted by: [REDACTED]
Location: [REDACTED]
Test performed by: [REDACTED]

Lab and Collection

SURGICAL PATHOLOGY (Order [REDACTED]) on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order [REDACTED]) on [REDACTED] - Order Result History Report

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Reviewed
Result Status:		

This result is currently not released to [REDACTED]

[Display Full Result Report](#)

[Display Order Report](#)

Source: NCI Genomic Data Commons file a63bc8c1-2faf-41f5-a302-11ece278ec9d (TCGA-IA-A40Y.CD072C5A-22CF-43CA-A903-2B1C0D794D59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).